FM case AD12172 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/a518dee9-29a2-4ce6-a866-ac89a20ce05f

Male, 58.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the biliary tract; metastasis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
